Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A01Q, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A01Q-01A (Primary Tumor).

TCGA #:

Sample ID #:

Diagnosis:

This is a poorly differentiated adenocarcinoma of the ascending colon with extensive anaplastic areas of solid carcinoma, with a histopathological grade G3 to 4 differentiation, with ulcerations of the inner tumor surface, with necroses, with peritumorous, chronic recurrent inflammation, with tumor infiltration in the layers of the colon wall as far as the subserous fatty connective tissue, with carcinomatous lymphangiosis, with moderate chronic lymphadenitis of the tumor-free lymph nodes (0/16), as well as tumor-free overview sections from the resection margins and from the reticular fatty tissue.

According to these prepared sections, the tumor spread of the colon carcinoma corresponds to the tumor stage pT3, pN2, MX, L1, R0
10+

100-0-3

adenocarcinoma, nos 8140/3

Site: ascending colon C18.2 lw 3/30/11

5/11/11

Source: NCI Genomic Data Commons file 7037d22d-8692-4b72-81ec-6002b462d2a1 (TCGA-AA-A01Q.C5E7082D-B5A0-4BF7-B929-9F6715A02276.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).